Somatic mutation profile of tumor specimen TCGA-AB-2941-03A (aliquot TCGA-AB-2941-03A-01W-0745-08) from TCGA case TCGA-AB-2941, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.9 years (26,998 days).
Specimen TCGA-AB-2941-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee4eced4-63e1-49f4-9d05-ecc8a2764415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2941-11A (Solid Tissue Normal), aliquot TCGA-AB-2941-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60577b06-293d-47b2-93ad-d8bc95690212

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITIH5 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113898501; called by muse, mutect2, varscan2
- TNR | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as rs760449162, COSV54899028; called by muse, mutect2, varscan2
- NPHS1 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
